Somatic mutation profile of tumor specimen TCGA-D8-A27I-01A (aliquot TCGA-D8-A27I-01A-11D-A16D-09) from TCGA case TCGA-D8-A27I, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 58.4 years (21,327 days).
Specimen TCGA-D8-A27I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a74b540a-933e-4cbc-a9e9-b02ba6c06bfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27I-10A (Blood Derived Normal), aliquot TCGA-D8-A27I-10A-02D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9351b944-20ff-4258-84dc-0dfa69507141

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53962247, COSV53967018; called by muse, mutect2, varscan2
- AHRR | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1050526137, COSV57084560; called by muse, mutect2, varscan2
- CD200R1 | c.334G>T p.D112Y (on ENST00000471858 / NM_170780.3; = p.D135Y on NM_138806.4) | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55599974, COSV99867749; called by muse, mutect2, varscan2
- CNTRL | c.5073G>A p.M1691I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53045516; called by muse, mutect2
- GTSE1 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.447); catalogued as COSV71889004; called by muse, mutect2, varscan2
- KLB | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758019530, COSV57301018; called by muse, mutect2, varscan2
- LGALS2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs763088523, COSV50755577, COSV50760238; called by muse, mutect2, varscan2
- MAP3K20 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.596); catalogued as COSV100919416; called by muse, mutect2
- MBNL1 | c.895A>G p.K299E (on ENST00000282486 / NM_207293.2; = p.K281E on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56826378; called by muse, mutect2, varscan2
- OR2T33 | c.940A>G p.N314D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58814881; called by muse, mutect2, varscan2
- PCDHGB1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV53925147; called by muse, mutect2, varscan2
- PLVAP | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs776368180, COSV53084355; called by muse, mutect2, varscan2
- POGZ | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as COSV55034239; called by muse, mutect2, varscan2
- PRDX5 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1184442007, COSV99134486; called by muse, mutect2
- RYR2 | c.5391A>T p.E1797D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as COSV63676553; called by muse, mutect2, varscan2
- SCN8A | c.3008G>A p.R1003H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752402332, COSV61979145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1G | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs267604464, COSV55598030; called by muse, mutect2, varscan2
- TMPRSS15 | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1336581675, COSV53037779; called by muse, mutect2
- TTLL6 | c.2667G>C p.E889D (on ENST00000393382 / NM_001130918.3; = p.E582D on NM_173623.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); catalogued as COSV64976741; called by muse, mutect2
- USP47 | c.2879A>G p.D960G (on ENST00000399455 / NM_001372095.1; = p.D872G on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV60462465; called by muse, mutect2, varscan2
- ZBTB7B | c.922G>C p.D308H (on ENST00000292176; = p.D342H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV99420910; called by muse, mutect2
- ZNF425 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs549520699, COSV65201012; called by muse, mutect2, varscan2
- CDH1 | c.497del p.N166Mfs*49 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- LRCH3 | c.794_795del p.K265Sfs*5 | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | called by mutect2, pindel, varscan2
- ANKRD40 | c.531G>T p.R177= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99560398; called by muse, mutect2
- CD177 | c.1236C>T p.G412= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1001220105, COSV100945874; called by muse, mutect2, varscan2
- CSPP1 | c.2145A>G p.T715= (on ENST00000676605; = p.T674= on NM_024790.6) | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV51582549; called by muse, mutect2, varscan2
- ELP1 | c.1896C>T p.I632= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV65897096; called by muse, mutect2, varscan2
- GABRA1 | c.1125C>T p.Y375= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV50101572; called by muse, mutect2, varscan2
- GPRC6A | c.288G>C p.G96= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV59952400; called by muse, mutect2, varscan2
- IL18 | c.315G>A p.E105= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99737039; called by muse, mutect2, varscan2
- MEGF10 | c.3270T>C p.N1090= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV57247659; called by muse, mutect2, varscan2
- SLC22A12 | c.783G>T p.L261= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV60571557; called by muse, mutect2, varscan2
